Gene-level copy-number profile of tumor specimen TCGA-CV-A45X-01A from TCGA case TCGA-CV-A45X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.8 years (17,464 days).
Specimen TCGA-CV-A45X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.51716304-6b4b-4507-a746-11d37b89e7fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A45X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/36fc422c-fecb-48d5-973b-a5d576289bef

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,080; copy number 2: 8,457; copy number 3: 29,751; copy number 4: 13,200; copy number 5: 4,068; copy number 6: 1,052; copy number 7: 1,004; copy number 8: 239; copy number 9: 129; copy number 10: 611; copy number 11: 114; copy number 22: 85; copy number 23: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A45X-01A-21D-A253-01): tumor purity 0.34, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,166 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,429,903–60,945,073, 14 genes, copy number 7: AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1.
- chr7:70,972–42,932,214, 738 genes, copy number 10–23 (within-gene range 6–23) (broad region; genes not listed).
- chr7:42,918,741–42,920,084, 1 gene, copy number 10: AC010132.2.
- chr8:35,235,475–35,796,550, 1 gene, copy number 8 (within-gene range 5–8): UNC5D.
- chr8:35,525,176–37,779,768, 36 genes, copy number 8: LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP.
- chr8:115,408,496–125,091,819, 141 genes, copy number 7–9 (broad region; genes not listed).
- chr10:30,299,569–34,815,325, 81 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr10:34,965,069–35,608,935, 17 genes, copy number 9: PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4.
- chr11:66,563,464–72,209,241, 216 genes, copy number 8–22 (within-gene range 3–22) (broad region; genes not listed).
- chr14:21,962,819–22,499,749, 70 genes, copy number 8 (broad region; genes not listed).
- chr18:29,629,842–29,650,440, 1 gene, copy number 8: AC117569.2.
- chr22:15,290,718–21,744,108, 325 genes, copy number 7 (broad region; genes not listed).
- chr22:21,957,025–29,061,844, 340 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:38,111,495–40,636,719, 90 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:48,044,710–50,801,309, 95 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
